CCDI case PBCADE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2afb0522-b02d-4150-b6a8-29f2eadc7132

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neuroepithelioma, NOS: ICD-O-3 morphology code: 9503/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 10.4 years (3,788 days).

Biospecimens (3 samples)
- Sample 0DM1JG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DM1JO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DM1K0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
